Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A822, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A822-01A (Primary Tumor).

Date receiving:

Translate on

from the original pathology evaluated on

LEFT ADRENAL

Macroscopy

The laboratory received a surgical specimen with a weight of 236g. This surgical specimen measures 9.5x8x5.5 cm. It consist of a adrenal gland compressed in the periphery because the presence a tumor mass (4.5x3.5x9 cm) relatively well limited by a capsule. This tumor appears multi-nodular with necrosis in the centre.

Microscopy

LEFT ADRENAL:

The above described mass corresponds to a malignant pheochromocytoma.

PASS score:

Feature	Score if present (no. of points assigned)
Large nests or diffuse growth (>10% of tumor volume)	2
Central (middle of large nests) or confluent tumor necrosis (not degenerative change)	2
High cellularity	2
Cellular monotony	0
Tumor cell spindling (even if focal)	0
Mitotic figures >3/10 HPF	0
Atypical mitotic figure(s)	0
Extension into adipose tissue	2
Vascular invasion	1
Capsular invasion	1
profound nuclear pleomorphism	1
Nuclear hyperchromasia	1
Total	12

This result supports the diagnosis of malignant pheochromocytoma.

Conclusion:

Pheochromocytoma

Absence of disease in 2 small lymph nodes.

ICD-O-3
Pheochromocytoma,
malignant 8700/3
Site ① Adrenal gland NOS
C74.9

JW 10/17/13

Source: NCI Genomic Data Commons file 5c1b9ce4-9946-4436-b0fb-d5e7d900196d (TCGA-WB-A822.AEE5206D-F4EC-4B2B-99A4-F60BC3C6EF22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).